Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5768, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5768-01A (Primary Tumor).

TCGA-CH-5768

Diagnosis

1. Multifocal and pluriform adenocarcinoma of the prostate with separate foci in the transitional zone and in the peripheral zone on both sides. Maximum tumor spread in the transitional zone on the right: 2 cm. Marked perineural invasion. Extraprostatic left rectolateral tumor growth with infiltration of the periprostatic fatty tissue. No identifiable invasion of the vessels. Tumor-free seminal vesicles.
2. Tumor-free fatty tissue.
3. Tumor-free prostate tissue and bundle of cross-striated muscle.
4. Three tumor-free lymph nodes.
5. Two tumor-free lymph nodes.
6. One tumor-free lymph node.
7. Three tumor-free lymph nodes.
8. Six tumor-free lymph nodes.
9. One tumor-free lymph node.

Remark

The tumor is classified as follows:

pT3a, pN0 (0/16), L0, V0; Gleason 2+4 = 6 with tertiary Gleason 3 portion (approx. 50% Gleason 2, 30% Gleason 4).

In the apex and the right rectolateral side, carcinoma cells extend to the artificial (yellow highlighted) margin of the preparation.

Compare here the material sent in separately for frozen section analysis with the XXXXX. The other preparation margins are tumor-free.

Source: NCI Genomic Data Commons file 73afb4be-4e8e-41f1-b489-74cfe8bbe340 (TCGA-CH-5768.619201A3-BFE0-473C-83F2-76028455FCB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).